Somatic mutation profile of tumor specimen TCGA-UY-A78M-01A (aliquot TCGA-UY-A78M-01A-21D-A34U-08) from TCGA case TCGA-UY-A78M, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 81.3 years (29,706 days).
Specimen TCGA-UY-A78M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8360e32-eaef-4103-a953-2d3cefcc5033.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UY-A78M-10A (Blood Derived Normal), aliquot TCGA-UY-A78M-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/70ac32ba-ffab-43e2-b343-125846bb9de0

The open-access MAF lists 153 somatic variants for this specimen: 115 protein-altering or splice-affecting, 34 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 93, Silent 34, Nonsense Mutation 14, Frame Shift Del 2, Splice Site 2, Frame Shift Ins 2, 5'UTR 2, RNA 1, Splice Region 1, 3'Flank 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 21/65 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SCN5A | c.1135C>T p.Q379* | Nonsense Mutation (SNP) | VAF 12/23 reads (52%) | catalogued as rs1553704878, COSV61124572; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.839G>C p.R280T | Missense Mutation (SNP) | VAF 16/25 reads (64%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCG8 | c.722C>G p.S241C | Missense Mutation (SNP) | VAF 58/165 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV55390739, COSV55394488; called by muse, mutect2, varscan2
- ACSM5 | c.1172C>T p.S391F | Missense Mutation (SNP) | VAF 60/225 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.78); catalogued as COSV59372883; called by muse, mutect2, varscan2
- ACTB | c.439C>A p.R147S | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV100079717, COSV59319465; called by muse, mutect2, varscan2
- AGBL1 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs775341691, COSV69803865; called by muse, mutect2, varscan2
- ANKRD36B | c.2656A>T p.N886Y | Missense Mutation (SNP) | VAF 4/67 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as COSV51531188; called by muse, mutect2
- ARHGAP11B | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 32/51 reads (63%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.783); catalogued as COSV70288403; called by muse, mutect2, varscan2
- BAP1 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56236816; called by muse, varscan2
- BBS7 | c.1271C>T p.S424F | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV52657664; called by muse, mutect2, varscan2
- BNIP5 | c.1669-1G>C p.X557_splice | Splice Site (SNP) | VAF 19/73 reads (26%) | catalogued as COSV71325665; called by muse, mutect2, varscan2
- C11orf16 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.501); catalogued as COSV58167801; called by muse, mutect2, varscan2
- C15orf39 | c.2057C>T p.S686F | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); catalogued as COSV62297197; called by muse, mutect2, varscan2
- C1orf74 | c.293A>G p.E98G | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1432119667, COSV50554882; called by muse, mutect2, varscan2
- C8orf82 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374436642; called by muse, mutect2, varscan2
- CCDC18 | c.3250G>C p.E1084Q (on ENST00000343253 / NM_001306076.1; = p.E1085Q on NM_206886.4) | Missense Mutation (SNP) | VAF 83/120 reads (69%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.943); catalogued as COSV58144966; called by muse, mutect2, varscan2
- CCL7 | c.89C>T p.T30I | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.91); PolyPhen benign (0.027); catalogued as rs370016796; called by muse, mutect2, varscan2
- CCNT2 | c.1902G>A p.M634I | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.68); PolyPhen benign (0.045); catalogued as COSV51474421; called by muse, varscan2
- CFAP94 | c.90G>A p.E30= (on ENST00000320267 / NM_001352064.2; = p.E36= on NM_018272.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 16/57 reads (28%) | catalogued as COSV57233888; called by muse, mutect2, varscan2
- CHPT1 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749005591, COSV57533886; called by muse, mutect2, varscan2
- CLTC | c.3559G>C p.E1187Q | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV52249269; called by muse, mutect2
- COL7A1 | c.8000C>T p.P2667L | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs377015274; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSCAM | c.5570G>T p.S1857I | Missense Mutation (SNP) | VAF 102/144 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV68029630; called by muse, mutect2, varscan2
- DSTYK | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 100/153 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV65687113; called by muse, mutect2, varscan2
- E2F5 | c.906C>G p.I302M | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as COSV56274295, COSV56275449, COSV56275736; called by muse, mutect2, varscan2
- EAPP | c.437G>A p.R146K | Missense Mutation (SNP) | VAF 47/84 reads (56%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as rs1333612794, COSV51652203; called by muse, mutect2, varscan2
- ECM2 | c.895C>T p.R299* | Nonsense Mutation (SNP) | VAF 9/91 reads (10%) | catalogued as rs138357265; called by muse, mutect2, varscan2
- EFCAB5 | c.2881C>G p.L961V | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57932533; called by muse, varscan2
- ESS2 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as COSV50082238, COSV99324015; called by muse, mutect2, varscan2
- FAM83D | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as rs1347405241, COSV99464911; called by muse, mutect2
- FAM90A1 | c.523G>C p.D175H | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV56713102; called by muse, mutect2, varscan2
- FKBP6 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as COSV52720182; called by muse, mutect2, varscan2
- FLG | c.3725C>G p.S1242C | Missense Mutation (SNP) | VAF 32/750 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.208); catalogued as COSV64242619, COSV64243917; called by muse, mutect2
- GLI1 | c.1474C>G p.L492V | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.594); catalogued as COSV57364137; called by muse, mutect2, varscan2
- GMPPB | c.844G>C p.D282H | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as COSV57539178; called by muse, mutect2, varscan2
- GRID2 | c.934C>G p.P312A | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.242); catalogued as COSV56218236, COSV56225480; called by muse, mutect2, varscan2
- HELZ2 | c.3535G>A p.G1179R (on ENST00000467148 / NM_001037335.2; = p.G610R on NM_033405.3) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.054); catalogued as COSV100915405; called by muse, mutect2
- IGSF9 | c.2032G>A p.E678K (on ENST00000368094 / NM_001135050.2; = p.E662K on NM_020789.4) | Missense Mutation (SNP) | VAF 20/404 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.111); catalogued as COSV100829621, COSV63640817; called by muse, mutect2
- IGSF9 | c.292C>G p.L98V | Missense Mutation (SNP) | VAF 105/123 reads (85%) | SIFT tolerated (0.3); PolyPhen benign (0.193); catalogued as COSV63640825; called by muse, mutect2, varscan2
- KCNH4 | c.1054G>C p.E352Q | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV52918922; called by muse, mutect2, varscan2
- KIAA1522 | c.478C>G p.R160G (on ENST00000373480 / NM_001198972.2; = p.R219G on NM_020888.3) | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs764978928, COSV53865701; called by muse, mutect2, varscan2
- KIF27 | c.4006C>G p.R1336G | Missense Mutation (SNP) | VAF 60/150 reads (40%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.042); catalogued as COSV52829133; called by muse, mutect2, varscan2
- KMT2D | c.3067C>T p.Q1023* | Nonsense Mutation (SNP) | VAF 13/41 reads (32%) | catalogued as COSV99976784; called by muse, mutect2, varscan2
- LAD1 | c.626C>G p.S209* | Nonsense Mutation (SNP) | VAF 21/256 reads (8%) | catalogued as COSV100943758; called by muse, mutect2
- LILRA6 | c.913G>T p.E305* | Nonsense Mutation (SNP) | VAF 14/132 reads (11%) | catalogued as COSV54440005, COSV99556883; called by muse, varscan2
- LIMK1 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs11541656, COSV60280908; called by muse, mutect2, varscan2
- LYZL2 | c.574G>T p.E192* (on ENST00000375318; = p.E146* on NM_183058.3) | Nonsense Mutation (SNP) | VAF 24/291 reads (8%) | catalogued as COSV100940493; called by muse, mutect2
- MAGIX | c.323A>C p.Q108P | Missense Mutation (SNP) | VAF 22/322 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.67); catalogued as COSV66256197; called by muse, mutect2
- MDN1 | c.4967C>T p.T1656I | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV65524315; called by muse, mutect2, varscan2
- METTL3 | c.1540C>A p.P514T | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52969927; called by muse, mutect2, varscan2
- MFSD2A | c.1597G>A p.E533K (on ENST00000372809 / NM_001136493.3; = p.E520K on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV65686000; called by muse, mutect2, varscan2
- MLN | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 65/135 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.334); catalogued as COSV56475462; called by muse, mutect2, varscan2
- MME | c.1871A>G p.Y624C | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.968); catalogued as rs1352030479, COSV64708552; called by muse, mutect2
- MUC2 | c.2396C>T p.T799M | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); catalogued as rs556795222; called by muse, mutect2, varscan2
- NKRF | c.1753C>A p.Q585K | Missense Mutation (SNP) | VAF 91/249 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.313); catalogued as COSV58662112; called by muse, mutect2, varscan2
- NKRF | c.88C>T p.Q30* | Nonsense Mutation (SNP) | VAF 10/95 reads (11%) | catalogued as COSV100441370, COSV58662629; called by muse, mutect2, varscan2
- NUP153 | c.1401G>T p.M467I | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.025); catalogued as COSV50453270; called by muse, mutect2, varscan2
- NVL | c.1759G>C p.E587Q | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.017); catalogued as COSV55873635; called by muse, mutect2, varscan2
- OR4C12 | c.784A>T p.T262S | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.255); catalogued as COSV58860429; called by muse, mutect2, varscan2
- OR4C6 | c.743T>A p.F248Y | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.498); catalogued as rs780526427, COSV58604830, COSV58605536; called by muse, mutect2, varscan2
- OR4X1 | c.272C>G p.S91C | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100186637, COSV60723240; called by muse, mutect2, varscan2
- PAGE1 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.972); catalogued as COSV65998095; called by muse, mutect2
- PCDH18 | c.79G>C p.G27R | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.49); catalogued as rs761594712, COSV61269715; called by muse, mutect2, varscan2
- PCDHGB3 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53921139; called by muse, mutect2, varscan2
- PEX6 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV99769405; called by muse, mutect2, varscan2
- PKD1L1 | c.6966-1G>C p.X2322_splice | Splice Site (SNP) | VAF 34/129 reads (26%) | catalogued as COSV51843368; called by muse, mutect2, varscan2
- PLCE1 | c.4891G>A p.D1631N | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.129); catalogued as COSV53348436, COSV53358128; called by muse, mutect2, varscan2
- PLXNB2 | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1384258254, COSV63782810; called by muse, mutect2, varscan2
- RAB32 | c.374A>T p.D125V | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62249305; called by muse, mutect2, varscan2
- RASGRF1 | c.1196C>T p.T399M | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1234815073, COSV69181774; called by muse, mutect2, varscan2
- RBBP8 | c.1363G>T p.E455* | Nonsense Mutation (SNP) | VAF 7/90 reads (8%) | catalogued as COSV100506993, COSV100507454; called by muse, mutect2
- REV3L | c.8152G>A p.D2718N | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV62620721; called by muse, varscan2
- REV3L | c.8090G>C p.R2697T | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62615936; called by muse, varscan2
- RFTN2 | c.634G>C p.E212Q | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.898); catalogued as COSV54387322, COSV54390263; called by muse, mutect2, varscan2
- RHOB | c.282C>A p.N94K | Missense Mutation (SNP) | VAF 51/191 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55356219, COSV55356727; called by muse, mutect2, varscan2
- RIPK4 | c.1498G>T p.E500* (on ENST00000352483; = p.E452* on NM_020639.3) | Nonsense Mutation (SNP) | VAF 138/186 reads (74%) | catalogued as COSV100204528; called by muse, mutect2, varscan2
- ROBO2 | c.2661G>T p.R887S | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59920355; called by muse, mutect2, varscan2
- ROCK2 | c.865G>C p.V289L | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as COSV55080992; called by muse, mutect2, varscan2
- SARDH | c.789G>C p.Q263H | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); catalogued as COSV53834421; called by muse, mutect2, varscan2
- SARS1 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 17/171 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV52321694; called by muse, mutect2, varscan2
- SEMA3G | c.502G>A p.G168R | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99201828; called by muse, mutect2, varscan2
- SESTD1 | c.698C>A p.S233* | Nonsense Mutation (SNP) | VAF 39/77 reads (51%) | catalogued as COSV100090122; called by muse, mutect2, varscan2
- SIM1 | c.1096G>A p.D366N | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.288); catalogued as COSV53493822; called by muse, mutect2, varscan2
- SLC9A3 | c.2130C>G p.I710M | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.177); catalogued as rs941160765, COSV53802523; called by muse, mutect2, varscan2
- SSH2 | c.3493G>C p.E1165Q | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.025); catalogued as COSV52175302; called by muse, mutect2, varscan2
- STK3 | c.1012C>T p.R338W | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as rs776913859, COSV69222777; called by muse, mutect2, varscan2
- STK32B | c.1157G>T p.R386L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.024); catalogued as COSV51497036; called by muse, mutect2, varscan2
- STK36 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 23/30 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV55308283; called by muse, mutect2, varscan2
- STRN4 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54419513; called by muse, mutect2, varscan2
- SUGP1 | c.1643G>A p.R548H | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs552135971, COSV55922239; called by muse, mutect2, varscan2
- TAF3 | c.1235G>C p.G412A | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100719791, COSV60208186; called by muse, mutect2, varscan2
- TAS2R16 | c.141G>A p.M47I | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.364); catalogued as COSV50797636; called by muse, mutect2, varscan2
- TAZ | c.469G>A p.V157I | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs782173851, COSV54796646; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TBC1D15 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.26); catalogued as COSV59850535; called by muse, mutect2, varscan2
- TDGF1 | c.506C>G p.S169C | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.87); catalogued as COSV56126955; called by muse, mutect2, varscan2
- TENM1 | c.5815C>T p.P1939S | Missense Mutation (SNP) | VAF 67/136 reads (49%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.94); catalogued as COSV64435995; called by muse, mutect2, varscan2
- TERF1 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV52578558, COSV99400851; called by muse, mutect2, varscan2
- TMEM8B | c.818C>T p.T273M | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs141283034; called by muse, mutect2
- TMEM94 | c.2725C>T p.Q909* | Nonsense Mutation (SNP) | VAF 37/118 reads (31%) | catalogued as COSV58597447; called by muse, mutect2, varscan2
- TNXB | c.9814G>A p.E3272K (on ENST00000647633; = p.E3025K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.354); catalogued as rs1355021413, COSV64482310; called by muse, mutect2, varscan2
- TUBGCP3 | c.196C>T p.R66* | Nonsense Mutation (SNP) | VAF 27/260 reads (10%) | catalogued as rs769171258, COSV99996466; called by muse, mutect2, varscan2
- UNC13B | c.2725G>C p.E909Q | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV65936027; called by muse, mutect2, varscan2
- USP28 | c.2077G>T p.E693* | Nonsense Mutation (SNP) | VAF 76/352 reads (22%) | catalogued as COSV50179086, COSV99134399; called by muse, mutect2, varscan2
- VAT1L | c.362A>G p.E121G | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.523); catalogued as COSV56822831; called by muse, mutect2
- VPS13B | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62021842; called by muse, mutect2
- WASF1 | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as COSV99660981; called by muse, mutect2, varscan2
- WDPCP | c.1171A>G p.I391V | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.045); catalogued as COSV55424516; called by muse, mutect2, varscan2
- YAP1 | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV56776426; called by muse, mutect2, varscan2
- ZNF470 | c.801G>C p.Q267H | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV57969593; called by muse, mutect2, varscan2
- BAP1 | c.818_839del p.T273Sfs*55 | Frame Shift Del (DEL) | VAF 5/45 reads (11%) | called by mutect2, pindel
- FAT3 | c.5465dup p.F1823Vfs*20 | Frame Shift Ins (INS) | VAF 9/39 reads (23%) | called by mutect2, pindel, varscan2
- PSIP1 | c.255_256insCT p.N86Lfs*6 | Frame Shift Ins (INS) | VAF 29/69 reads (42%) | called by mutect2, pindel, varscan2
- RUNX1 | c.443_445dup p.L148_T149insM (on ENST00000344691 / NM_001001890.3; = p.L175_T176insM on NM_001754.5) | In Frame Ins (INS) | VAF 80/128 reads (63%) | called by mutect2, pindel, varscan2
- SPATA4 | c.740del p.P247Lfs*11 | Frame Shift Del (DEL) | VAF 24/66 reads (36%) | called by mutect2, pindel*, varscan2
- ACTN2 | c.1398G>A p.Q466= | Silent (SNP) | VAF 37/62 reads (60%) | catalogued as COSV63976347; called by muse, mutect2, varscan2
- APOL6 | c.927G>A p.G309= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV68749581; called by muse, mutect2
- BRPF3 | c.1212C>T p.I404= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV60208209; called by muse, mutect2, varscan2
- BSN | c.4218C>T p.S1406= | Silent (SNP) | VAF 20/222 reads (9%) | catalogued as rs772911326, COSV56521713; called by muse, mutect2
- CLEC18B | c.273C>T p.I91= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV100375615; called by mutect2, varscan2
- CNOT3 | c.1716G>A p.L572= | Silent (SNP) | VAF 19/175 reads (11%) | catalogued as rs1315255632, COSV55365209; called by muse, mutect2, varscan2
- EFCAB5 | c.2838C>A p.L946= | Silent (SNP) | VAF 46/152 reads (30%) | catalogued as COSV57932526, COSV57934655; called by muse, varscan2
- GPC6 | c.1266C>T p.C422= | Silent (SNP) | VAF 35/103 reads (34%) | catalogued as COSV65518882; called by muse, mutect2, varscan2
- IL12RB1 | c.825G>A p.A275= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs141737618; called by muse, mutect2, varscan2
- IMP3 | c.300C>T p.F100= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs548417463, COSV59189318; called by muse, mutect2, varscan2
- JMJD6 | c.111G>T p.L37= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV100372841; called by muse, mutect2
- KCNQ4 | c.594C>T p.F198= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as rs1416040314, COSV61273941; called by muse, mutect2
- KIF23 | c.2112C>T p.L704= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as COSV52981044; called by muse, mutect2, varscan2
- LAMA2 | c.243G>A p.P81= | Silent (SNP) | VAF 36/87 reads (41%) | catalogued as rs766642494, COSV70344877; called by muse, mutect2, varscan2
- LMAN1 | c.117C>T p.V39= | Silent (SNP) | VAF 39/107 reads (36%) | catalogued as COSV51827675; called by muse, mutect2, varscan2
- MICALL1 | c.2184C>T p.L728= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as rs192522420, COSV53241611; called by muse, mutect2, varscan2
- MRGPRX4 | c.177C>T p.N59= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as rs750419471, COSV58590972; called by muse, mutect2, varscan2
- MUC20 | c.1341G>A p.T447= | Silent (SNP) | VAF 8/91 reads (9%) | catalogued as rs752636906, COSV57852994; called by muse, mutect2
- OPLAH | c.1644C>T p.D548= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV101470697, COSV70678871; called by muse, mutect2
- PCDH19 | c.729C>T p.Y243= | Silent (SNP) | VAF 25/181 reads (14%) | catalogued as rs1166554052, CM106011, COSV55266179; called by muse, mutect2, varscan2
- PROX1 | c.1983G>T p.L661= | Silent (SNP) | VAF 84/135 reads (62%) | catalogued as COSV54780754; called by muse, mutect2, varscan2
- RANBP17 | c.852T>C p.V284= | Silent (SNP) | VAF 16/111 reads (14%) | catalogued as COSV66652884; called by muse, mutect2, varscan2
- RUNX3 | c.849G>A p.T283= | Silent (SNP) | VAF 65/95 reads (68%) | catalogued as rs779004787, COSV58244721; called by muse, mutect2, varscan2
- SLC6A3 | c.1536C>T p.T512= | Silent (SNP) | VAF 54/148 reads (36%) | catalogued as rs754071989, COSV54365991; called by muse, mutect2, varscan2
- SNF8 | c.474C>T p.F158= | Silent (SNP) | VAF 15/104 reads (14%) | catalogued as rs943815268, COSV51727139; called by muse, mutect2, varscan2
- STAG1 | c.72C>T p.S24= | Silent (SNP) | VAF 32/108 reads (30%) | catalogued as COSV52614761; called by muse, mutect2, varscan2
- SYT3 | c.831G>A p.G277= | Silent (SNP) | VAF 22/143 reads (15%) | catalogued as COSV58897566, COSV58899111; called by muse, mutect2, varscan2
- TNFRSF11B | c.810C>A p.I270= | Silent (SNP) | VAF 11/134 reads (8%) | catalogued as COSV52072007, COSV99816535; called by muse, mutect2
- TOMM20L | c.87C>G p.L29= | Silent (SNP) | VAF 12/19 reads (63%) | catalogued as COSV62878362, COSV62878426; called by muse, mutect2, varscan2
- UXT | c.6G>A p.A2= | Silent (SNP) | VAF 31/54 reads (57%) | catalogued as COSV60039700; called by muse, mutect2, varscan2
- VAV2 | c.150C>G p.L50= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV100895483; called by muse, varscan2
- VDAC2 | c.831G>A p.K277= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV53686640; called by muse, mutect2, varscan2
- WWC3 | c.1755C>T p.N585= | Silent (SNP) | VAF 27/95 reads (28%) | catalogued as rs144439055, COSV66504597; called by muse, mutect2, varscan2
- ZNF516 | c.3339C>T p.L1113= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV71587256; called by muse, mutect2, varscan2
- JMJD6 | c.-2G>A | 5'UTR (SNP) | VAF 22/58 reads (38%) | catalogued as COSV57970354; called by muse, mutect2, varscan2
- NBPF7 | n.841G>C | RNA (SNP) | VAF 31/63 reads (49%) | called by muse, mutect2, varscan2
- OR5P2 | c.-1C>T | 5'UTR (SNP) | VAF 5/44 reads (11%) | catalogued as rs752256541, COSV100271154; called by muse, mutect2, varscan2
- RAB26 | chr16:2155059 C>T | 3'Flank (SNP) | VAF 13/57 reads (23%) | called by muse, mutect2, varscan2
